Surgical pathology report (de-identified scan), TCGA case TCGA-AO-A12E, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site MSKCC, specimen TCGA-AO-A12E-01A (Primary Tumor).

[page 2 of 3]
--- Report Electronically Signed Out ---

Special Studies:
Result

Special Stain

Comment

ER-C
PR-C
HER2-C
IMM RECUT
NEG CONT
NEG-HER2
AE1:AE3
AE1:AE3
IMM RECUT
NEG CONT
IMM RECUT
NEG CONT

Gross Description:

1). The specimen is received fresh labeled, " Right modified radical mastectomy with levels one axillary contents with level one and two", and consists of a breast measuring a 33.2 x 20.3 x 4.5 cm, with overlying skin ellipse measuring 11.2 x 2.6 cm, and without scar. The nipple measures 1.6 cm in diameter. The posterior surface of the breast is inked black and anterior inked yellow. The specimen is serially sectioned to reveal an ill-defined mass above the nipple area (12:00), measuring 2.3 x 1.5 x 1.3 cm. The mass is closed to the skin and 2 cm away from deep margin. There is fibrous tissue adjacent to the mass occupying the lower outer quadrant and lower inner quadrant. Multiple lymph nodes are noted in the axillary area, the largest one measures 1.2 cm in dimension. Representative sections are submitted.

Summary of sections:

NIP - nipple
BASE - nipple base
D - deep margin
T-mass
F- Fibrous tissue adjacent to the tumor
UIQ - upper inner quadrant
LIQ - lower inner quadrant
UOQ - upper outer quadrant
LOQ - lower outer quadrant
L1- lymph nodes (level 1)
L2- lymph nodes (level 2)

** Continued on next page **

[page 3 of 3]
31

Summary of Sections:

Part 1: SP: Right breast and axillary contents levels 1 and 2

Block	Sect.	Site	PCs
1		base	
1		d	1
9		f	9
3		L1	
2		L2	4
2		liq	4
1		ln	2
2		loq	1
1		nip	2
3		t	1
2		uiq	3
2		uoq	2
			0

** End of Report **

Source: NCI Genomic Data Commons file 6a8aaade-1733-4710-bb24-21645b0f1873 (TCGA-AO-A12E.332675C9-53CB-4244-8480-82E1546DA7F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).